Somatic mutation profile of tumor specimen TCGA-ZF-A9R4-01A (aliquot TCGA-ZF-A9R4-01A-11D-A38G-08) from TCGA case TCGA-ZF-A9R4, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 83.2 years (30,398 days).
Specimen TCGA-ZF-A9R4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff118af-1e5f-4536-b1ed-ace2df79ec57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-A9R4-10A (Blood Derived Normal), aliquot TCGA-ZF-A9R4-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a25d9743-d752-4069-9504-eb82c83ec1ff

The open-access MAF lists 273 somatic variants for this specimen: 208 protein-altering or splice-affecting, 61 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 61, Nonsense Mutation 20, Intron 3, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | catalogued as rs1057518951, COSV99267853; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 31/65 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs776846119, COSV59205460, COSV59217320; called by muse, mutect2, varscan2
- AADACL2 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 56/87 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62930727; called by muse, mutect2, varscan2
- ABCA9 | c.1909C>T p.Q637* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as rs1293166752, COSV100382786; called by muse, mutect2, varscan2
- ABCB8 | c.2094G>C p.K698N (on ENST00000297504 / NM_001282291.2; = p.K681N on NM_007188.5) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1177836124, COSV52505345; called by muse, mutect2, varscan2
- ABCC4 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV65313370; called by muse, mutect2, varscan2
- ACTB | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59316730; called by muse, mutect2, varscan2
- ACVR1 | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55119418; called by muse, mutect2, varscan2
- ADAMTS20 | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67129101, COSV67132697; called by muse, mutect2, varscan2
- ADAMTS9 | c.3254G>C p.R1085P | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV55781303, COSV55782439; called by muse, mutect2, varscan2
- ADAR | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 122/159 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1159444304, COSV52716234; called by muse, mutect2, varscan2
- ADCY9 | c.2272G>A p.E758K | Missense Mutation (SNP) | VAF 75/113 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as COSV53576157; called by muse, mutect2, varscan2
- ADD3 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.781); catalogued as COSV53322692; called by muse, mutect2, varscan2
- ADGRG4 | c.1197G>C p.K399N | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV54957670; called by muse, mutect2, varscan2
- AFG1L | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV64555989; called by muse, mutect2, varscan2
- AGO4 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64617317, COSV64617624; called by muse, mutect2, varscan2
- ANGEL1 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs766085089, COSV51873603; called by muse, mutect2, varscan2
- ANO8 | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs746119038, COSV50175056; called by muse, mutect2, varscan2
- AP002748.5 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV100567767, COSV59150804; called by muse, mutect2, varscan2
- AP3B1 | c.102C>G p.F34L | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54884964, COSV54895344; called by muse, mutect2, varscan2
- ARHGAP29 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53112616; called by muse, mutect2, varscan2
- ATAD5 | c.449A>C p.D150A | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV58975325; called by muse, mutect2, varscan2
- ATP2B1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1370730512, COSV99665319; called by muse, mutect2
- B4GALNT2 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV55928018; called by muse, mutect2
- BAZ2B | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 18/30 reads (60%) | catalogued as COSV100600465; called by muse, mutect2, varscan2
- BRD8 | c.1942G>A p.E648K (on ENST00000254900 / NM_139199.2; = p.E721K on NM_006696.4) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as COSV50150532; called by muse, mutect2, varscan2
- BTBD10 | c.1055G>C p.R352T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV53399412; called by muse, mutect2, varscan2
- C7orf50 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as COSV62475390; called by muse, mutect2, varscan2
- CAMSAP2 | c.1779C>G p.I593M (on ENST00000236925 / NM_001297707.2; = p.I582M on NM_203459.3) | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV52668324, COSV52671763; called by muse, mutect2, varscan2
- CARMIL2 | c.2638C>T p.Q880* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV58023795; called by muse, mutect2, varscan2
- CASP1 | c.542G>A p.G181E (on ENST00000436863 / NM_033292.4; = p.G160E on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62056726; called by muse, mutect2, varscan2
- CC2D1A | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV58783772; called by muse, mutect2, varscan2
- CCDC191 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 115/190 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV55560256, COSV55562546; called by muse, mutect2, varscan2
- CCIN | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV58724854; called by muse, mutect2, varscan2
- CDKN2A | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1060501269, COSV58682703, COSV58715254, COSV58723757; called by muse, varscan2
- CEP350 | c.2084C>G p.S695C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100854389; called by muse, mutect2, varscan2
- CERK | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV53451645; called by muse, mutect2, varscan2
- CFH | c.1403C>A p.A468D | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.522); catalogued as COSV66408861, COSV66409141; called by muse, mutect2, varscan2
- CHRNA7 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs376513096, COSV60970999, COSV60973740; called by muse, mutect2, varscan2
- CILP2 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752372369, COSV52275672; called by muse, mutect2, varscan2
- CLCN3 | c.1055C>A p.S352* | Nonsense Mutation (SNP) | VAF 48/57 reads (84%) | catalogued as COSV100641619; called by muse, mutect2, varscan2
- CLDN14 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs138008896; called by muse, mutect2, varscan2
- COL11A1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV62185129, COSV62195592; called by muse, mutect2, varscan2
- COL3A1 | c.3824G>C p.G1275A | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58589425, COSV58596842; called by muse, mutect2, varscan2
- CSGALNACT1 | c.852G>A p.R284= | Splice Region (SNP) | VAF 33/34 reads (97%) | catalogued as rs1442271362, COSV59978401; called by muse, mutect2, varscan2
- CUL1 | c.1821G>C p.Q607H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100296547, COSV57389212; called by muse, mutect2, varscan2
- CYP7A1 | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192994825, COSV56963946; called by muse, mutect2, varscan2
- DACT1 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759605025, COSV60021151; called by muse, mutect2, varscan2
- DAZAP1 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 32/38 reads (84%) | catalogued as COSV51831873, COSV51833701, COSV99245075; called by muse, mutect2, varscan2
- DCUN1D3 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 34/88 reads (39%) | catalogued as COSV100176755; called by muse, mutect2, varscan2
- DIPK1B | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.847); catalogued as COSV100765444; called by muse, mutect2, varscan2
- DNAJA4 | c.1081C>G p.Q361E (on ENST00000343789; = p.Q390E on NM_018602.3) | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51216966; called by muse, mutect2, varscan2
- DPP10 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 41/59 reads (69%) | catalogued as rs1405118520, COSV100060624, COSV59740747; called by muse, mutect2, varscan2
- ECPAS | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99397752; called by muse, mutect2, varscan2
- EHMT1 | c.1469G>A p.R490Q | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as rs756231112, COSV58375906; called by muse, mutect2, varscan2
- ELF3 | c.478+1_478+3del p.X160_splice | Splice Site (DEL) | VAF 16/34 reads (47%) | catalogued as rs995289305; called by mutect2, pindel, varscan2
- EMX2 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV71294641; called by muse, mutect2, varscan2
- ENTPD8 | c.1376A>T p.Q459L (on ENST00000371506 / NM_001033113.2; = p.Q422L on NM_198585.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.048); catalogued as COSV58162141; called by muse, mutect2, varscan2
- EPB41L4B | c.2366T>C p.M789T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV65803389; called by muse, mutect2
- ESF1 | c.1708A>G p.K570E | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.551); catalogued as rs918395453, COSV52521440; called by muse, mutect2, varscan2
- ESYT1 | c.2792C>T p.S931F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1489011954, COSV57273688; called by muse, mutect2, varscan2
- FAM13A | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV52003714; called by muse, mutect2, varscan2
- FAM89B | c.404C>T p.S135L (on ENST00000530349 / NM_001098785.2; = p.S122L on NM_152832.3) | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57079581; called by muse, mutect2, varscan2
- FERMT3 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs572874105, COSV54180420; called by muse, mutect2, varscan2
- FGG | c.783G>C p.L261F | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV60195574, COSV60196155; called by muse, mutect2, varscan2
- FNBP4 | c.1506G>T p.E502D | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV55449075; called by muse, mutect2, varscan2
- FPR3 | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 80/147 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.017); catalogued as COSV59330221; called by muse, mutect2, varscan2
- FRAS1 | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as rs748242409, COSV53615616; called by muse, mutect2, varscan2
- FTSJ3 | c.2447G>C p.G816A | Missense Mutation (SNP) | VAF 100/186 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750381400, COSV63790222, COSV63790296; called by muse, mutect2, varscan2
- FUT10 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV59658563; called by muse, mutect2, varscan2
- GLYR1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV58927327; called by muse, mutect2, varscan2
- GPR160 | c.707C>A p.S236Y | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV63473001; called by muse, mutect2, varscan2
- GREB1 | c.4227_4228insA p.F1410Ifs*2 | Frame Shift Ins (INS) | VAF 97/341 reads (28%) | catalogued as COSV52188625; called by mutect2, pindel, varscan2
- GRIA1 | c.852G>C p.K284N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53605922; called by muse, mutect2, varscan2
- HDAC3 | c.24C>G p.F8L | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV51837420; called by muse, mutect2, varscan2
- HDGFL2 | c.1796C>G p.S599* | Nonsense Mutation (SNP) | VAF 23/33 reads (70%) | catalogued as COSV100012149; called by muse, mutect2, varscan2
- HECTD4 | c.8227G>A p.E2743K | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1391798490, COSV101108353, COSV66388407; called by muse, mutect2, varscan2
- HESX1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766234350, CM1110145, COSV55843341, COSV55843561; called by muse, mutect2, varscan2
- HIP1 | c.727C>A p.L243I | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV61186567; called by muse, mutect2, varscan2
- IGHA1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs373374418; called by muse, mutect2, varscan2
- IGKV2D-24 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 87/143 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs1339145134; called by muse, mutect2, varscan2
- IGSF3 | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100604216; called by muse, mutect2, varscan2
- IL10RA | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99922923; called by muse, mutect2, varscan2
- INHA | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as COSV54720868; called by muse, mutect2, varscan2
- ITGAV | c.2830C>T p.Q944* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99654447, COSV99655126; called by muse, mutect2, varscan2
- KCNH4 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV52918205; called by muse, mutect2, varscan2
- KCNJ9 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.168); catalogued as rs1401123624, COSV58757583, COSV58758221; called by muse, mutect2, varscan2
- KDM2B | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.491); catalogued as rs782101520, COSV65640692; called by muse, mutect2, varscan2
- KLHL35 | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV66219381; called by muse, mutect2, varscan2
- KMT2D | c.15781C>T p.Q5261* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV56489777; called by muse, mutect2, varscan2
- KMT2D | c.14274T>A p.Y4758* | Nonsense Mutation (SNP) | VAF 45/108 reads (42%) | catalogued as COSV99978636; called by muse, mutect2, varscan2
- KPNA2 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs782088901, COSV57857925; called by muse, mutect2, varscan2
- KPNA2 | c.1107G>C p.Q369H | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.822); catalogued as COSV57857607; called by muse, mutect2, varscan2
- LCP2 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1424352216, COSV99252303; called by muse, mutect2, varscan2
- LGR5 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV57005515; called by muse, mutect2, varscan2
- LMAN1 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV51827217; called by muse, mutect2, varscan2
- LRP10 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62078370; called by muse, mutect2, varscan2
- LRRC8A | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs752652023, COSV52186209; called by muse, varscan2
- LTA4H | c.478G>C p.E160Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.088); catalogued as COSV57382750; called by muse, mutect2, varscan2
- MCM3AP | c.4606G>A p.E1536K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.265); catalogued as rs763070836, COSV52440427; called by muse, mutect2, varscan2
- MCM3AP | c.4543G>C p.E1515Q | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV52440434; called by muse, mutect2, varscan2
- MOB3C | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147799654; called by muse, mutect2, varscan2
- MSI2 | c.270G>A p.T90= | Splice Region (SNP) | VAF 29/119 reads (24%) | catalogued as COSV52359488; called by muse, mutect2, varscan2
- MTOR | c.6145G>C p.E2049Q | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV63872065, COSV63872289; called by muse, varscan2
- MTOR | c.6043G>C p.E2015Q | Missense Mutation (SNP) | VAF 75/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63872295; called by muse, varscan2
- MYH1 | c.5642C>T p.S1881F | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV56844220; called by muse, varscan2
- MYO5B | c.5131C>A p.Q1711K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53220452; called by muse, varscan2
- N4BP3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.532); catalogued as rs769104324, COSV51063058; called by muse, varscan2
- NAV3 | c.7090A>T p.S2364C (on ENST00000397909 / NM_001024383.2; = p.S2342C on NM_014903.6) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57083839; called by muse, mutect2, varscan2
- NCOA1 | c.258G>C p.E86D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.105); catalogued as COSV56038370; called by muse, varscan2
- NCOA1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs1299851303, COSV56045398, COSV56050311; called by muse, varscan2
- NCOR1 | c.5435C>T p.S1812F | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs1429917978, COSV51977064; called by muse, mutect2, varscan2
- NDFIP1 | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0.04); catalogued as COSV54074957; called by muse, mutect2, varscan2
- NEDD1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.556); catalogued as COSV57143876; called by muse, mutect2, varscan2
- NFXL1 | c.1721C>G p.S574C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV61199247, COSV61199824; called by muse, mutect2, varscan2
- NGEF | c.1215C>G p.F405L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV50925596, COSV99891191; called by muse, mutect2, varscan2
- NPAP1 | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); catalogued as COSV61507685, COSV61509041; called by muse, mutect2, varscan2
- NR1D2 | c.1726A>C p.K576Q | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV56992155; called by muse, mutect2, varscan2
- NTRK3 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs747624231, COSV58116750; called by muse, mutect2, varscan2
- OFD1 | c.717A>T p.E239D | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV60796290; called by muse, mutect2, varscan2
- OR1D5 | c.905G>A p.R302K | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs760903075, COSV101643412; called by mutect2, varscan2
- PAFAH2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.025); catalogued as rs1219279031, COSV65339587; called by muse, mutect2, varscan2
- PATJ | c.4558G>T p.E1520* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100333440; called by muse, mutect2, varscan2
- PATZ1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV53231207; called by muse, mutect2, varscan2
- PCDHB12 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 78/133 reads (59%) | catalogued as COSV99506955; called by muse, mutect2, varscan2
- PCDHB16 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 91/132 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV53363273; called by muse, mutect2, varscan2
- PDS5B | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV59728173; called by muse, mutect2, varscan2
- PEPD | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52287507; called by muse, mutect2, varscan2
- PEX13 | c.120G>C p.M40I | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54369963, COSV54370238; called by muse, mutect2, varscan2
- PGBD2 | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV61400305; called by muse, mutect2, varscan2
- PGLYRP2 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52994459; called by muse, mutect2, varscan2
- PHKA1 | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 32/36 reads (89%) | catalogued as COSV100262646; called by muse, mutect2, varscan2
- PIDD1 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs556597386, COSV57193526; called by muse, mutect2, varscan2
- PKN3 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52577208; called by muse, mutect2, varscan2
- PLIN4 | c.3171G>T p.R1057S (on ENST00000301286; = p.R1072S on NM_001367868.2) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV56692324; called by muse, mutect2, varscan2
- PLIN4 | c.2973G>A p.M991I (on ENST00000301286; = p.M1006I on NM_001367868.2) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs767174786, COSV56692337; called by muse, mutect2, varscan2
- POTEE | c.2567G>A p.G856D | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs776123470, COSV58232487; called by muse, mutect2, varscan2
- PPARGC1A | c.987G>C p.K329N | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV53528170; called by muse, mutect2, varscan2
- PPP2R5C | c.1137G>C p.K379N | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV58272204; called by muse, mutect2, varscan2
- PRMT8 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV54214729; called by muse, mutect2, varscan2
- PRPF4B | c.1487G>C p.R496T | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV61784368; called by muse, mutect2, varscan2
- PTPN1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs763558512, COSV65407193, COSV65408227; called by muse, mutect2, varscan2
- PTPN1 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65408230; called by muse, mutect2, varscan2
- PTPN21 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.022); catalogued as COSV60848710; called by muse, mutect2, varscan2
- PTPRU | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.367); catalogued as COSV60529054; called by muse, mutect2, varscan2
- PURA | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100495684; called by muse, mutect2, varscan2
- PYGL | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV53586338; called by muse, mutect2, varscan2
- QRICH2 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs151295247; called by muse, mutect2, varscan2
- RBM47 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV55930899, COSV55935977; called by muse, mutect2, varscan2
- RELN | c.9700C>G p.L3234V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV59005967; called by muse, mutect2, varscan2
- REV1 | c.3700G>C p.D1234H | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51485970; called by muse, mutect2, varscan2
- RHOB | c.84C>G p.D28E | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV55356247; called by muse, mutect2, varscan2
- RNF157 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV53944668; called by muse, mutect2, varscan2
- RNF31 | c.2265C>A p.D755E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60727038; called by muse, mutect2, varscan2
- RSPH4A | c.1195C>G p.H399D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99993983; called by muse, mutect2, varscan2
- SACM1L | c.1741G>T p.V581F | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV66612275; called by muse, mutect2, varscan2
- SCN2A | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV51839580, COSV51843394; called by muse, mutect2, varscan2
- SCUBE3 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); catalogued as COSV51457352; called by muse, mutect2, varscan2
- SEMA5A | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV66787697, COSV66794837, COSV66806797; called by muse, mutect2, varscan2
- SERPINB10 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV53073467; called by muse, mutect2, varscan2
- SERPINE1 | c.713C>T p.T238M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201327802, COSV56168926; called by muse, mutect2, varscan2
- SETD5 | c.3254G>A p.G1085E | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV56711707; called by muse, mutect2, varscan2
- SH3PXD2B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV61127338; called by muse, mutect2, varscan2
- SLC11A1 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.746); catalogued as rs760595815, COSV51917443; called by muse, mutect2, varscan2
- SLC45A1 | c.243G>C p.Q81H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV57095151, COSV57096036; called by muse, mutect2, varscan2
- SLC6A1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV55115825; called by muse, mutect2, varscan2
- SLC6A4 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55567231; called by muse, mutect2, varscan2
- SLC9B1 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 27/38 reads (71%) | catalogued as COSV99599328; called by muse, mutect2, varscan2
- SLF2 | c.3072G>C p.K1024N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs1564782643, COSV53274457; called by muse, mutect2, varscan2
- SORCS1 | c.2893C>A p.Q965K | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV53871089; called by muse, mutect2, varscan2
- SPATA31A1 | c.3978G>C p.K1326N | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs1290665587; called by muse, mutect2, varscan2
- SPEF2 | c.4723G>C p.E1575Q | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV57429580; called by muse, mutect2, varscan2
- STAG1 | c.2860G>C p.E954Q | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52611554, COSV52621646; called by muse, varscan2
- SVEP1 | c.9479C>A p.T3160K | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.655); catalogued as rs1252773220, COSV52839946; called by muse, mutect2
- SYNE1 | c.9653C>G p.S3218C (on ENST00000367255 / NM_182961.4; = p.S3225C on NM_033071.3) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.333); catalogued as COSV54998788; called by muse, mutect2, varscan2
- SYNE1 | c.4838C>T p.S1613L (on ENST00000367255 / NM_182961.4; = p.S1620L on NM_033071.3) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); catalogued as COSV54998834; called by muse, mutect2, varscan2
- SYT10 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV57341136; called by muse, mutect2, varscan2
- TAF1B | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV55156637; called by muse, mutect2, varscan2
- TAF6L | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV53668991; called by muse, mutect2, varscan2
- TEX2 | c.1475C>G p.P492R | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51978818, COSV51981697; called by muse, mutect2, varscan2
- TEX2 | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV51980691; called by muse, mutect2, varscan2
- TMEM203 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58807671; called by muse, mutect2, varscan2
- TP53 | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV52666570, COSV52937236, COSV53050140; called by muse, mutect2, varscan2
- TRIM4 | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as COSV62469412; called by muse, mutect2
- TRPC4 | c.1821C>G p.I607M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58990089, COSV58996576, COSV59002094; called by muse, mutect2, varscan2
- TRPC4 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59002119; called by muse, mutect2, varscan2
- TSHZ1 | c.1384G>A p.E462K (on ENST00000580243 / NM_001308210.2; = p.E417K on NM_005786.6) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as COSV59010604; called by muse, mutect2, varscan2
- TUBA4A | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV50278467; called by muse, mutect2, varscan2
- UBE2J1 | c.441C>G p.F147L | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV70561552; called by muse, mutect2, varscan2
- UCKL1 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs766254364, COSV62402992; called by mutect2, varscan2
- UGT1A9 | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 141/232 reads (61%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV60841030; called by muse, mutect2, varscan2
- USP28 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV50164922; called by muse, mutect2, varscan2
- VPS13B | c.1933C>G p.L645V | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV62020437; called by muse, mutect2, varscan2
- XDH | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV65149123; called by muse, mutect2, varscan2
- XIRP2 | c.9644C>G p.S3215C (on ENST00000628543; = p.S3390C on NM_152381.6) | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1010624973, COSV54704566; called by muse, mutect2, varscan2
- YIF1B | c.280G>A p.E94K (on ENST00000339413 / NM_001039673.3; = p.E79K on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as rs753986201, COSV56650917; called by muse, mutect2, varscan2
- ZBTB5 | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57040316, COSV57041393; called by muse, mutect2, varscan2
- ZFHX3 | c.3974C>G p.S1325* | Nonsense Mutation (SNP) | VAF 20/33 reads (61%) | catalogued as COSV99195743; called by muse, mutect2, varscan2
- ZMYM4 | c.2980C>G p.L994V | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV58911441; called by muse, mutect2, varscan2
- ZNF138 | c.517G>A p.D173N (on ENST00000307355 / NM_001367572.1; = p.D147N on NM_006524.4) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV56465535; called by muse, mutect2, varscan2
- ZNF19 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV55507789; called by muse, mutect2, varscan2
- ZNF383 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | catalogued as COSV61938721; called by muse, mutect2, varscan2
- ZNF626 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as rs187292121, COSV74129630; called by muse, mutect2, varscan2
- CDKN2A | c.119_137del p.A40Gfs*7 | Frame Shift Del (DEL) | VAF 38/115 reads (33%) | called by pindel, varscan2*
- EP300 | c.3529_3532del p.C1177Tfs*49 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | called by mutect2, pindel, varscan2
- OR5AR1 | c.185dup p.L63Pfs*8 | Frame Shift Ins (INS) | VAF 41/183 reads (22%) | called by mutect2, pindel, varscan2
- ABCB8 | c.933G>A p.L311= (on ENST00000297504 / NM_001282291.2; = p.L294= on NM_007188.5) | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs762741020, COSV52505310; called by muse, mutect2, varscan2
- ADD3 | c.1368G>A p.R456= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV53322709; called by muse, mutect2, varscan2
- ADIPOQ | c.387C>T p.P129= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV57859209, COSV57859244; called by muse, mutect2, varscan2
- ARHGAP26 | c.1659G>A p.Q553= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV50830588; called by muse, mutect2, varscan2
- BUB1 | c.771G>A p.Q257= | Silent (SNP) | VAF 52/77 reads (68%) | catalogued as COSV57064112; called by muse, mutect2, varscan2
- CLEC14A | c.828C>T p.G276= | Silent (SNP) | VAF 46/78 reads (59%) | catalogued as COSV60562739; called by muse, mutect2, varscan2
- DNAH5 | c.1899C>T p.L633= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV54229534; called by muse, mutect2, varscan2
- DNAJB14 | c.90C>T p.F30= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as rs1454795126, COSV56455322; called by muse, mutect2, varscan2
- GPR63 | c.957C>G p.L319= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV57741468; called by muse, mutect2, varscan2
- GRAMD4 | c.834C>A p.I278= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs375236476, COSV63030565; called by muse, mutect2, varscan2
- GTF2IRD2B | c.264G>A p.V88= | Silent (SNP) | VAF 68/197 reads (35%) | catalogued as COSV57032850; called by muse, mutect2, varscan2
- GTF3C3 | c.27C>A p.I9= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV55832388; called by muse, mutect2, varscan2
- H2AC20 | c.168C>G p.L56= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs1211675246, COSV58612156; called by muse, mutect2, varscan2
- HECTD1 | c.5463G>A p.L1821= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV67946690, COSV67948449; called by muse, mutect2, varscan2
- HEXIM1 | c.801C>T p.F267= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs780372202, COSV60177126; called by muse, mutect2, varscan2
- HLA-DMB | c.561G>A p.G187= | Silent (SNP) | VAF 37/66 reads (56%) | catalogued as rs1236693886, COSV66870798; called by muse, mutect2, varscan2
- IKZF1 | c.879C>T p.Y293= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1449573722, COSV100498111; called by muse, mutect2, varscan2
- INTS3 | c.459G>A p.V153= | Silent (SNP) | VAF 55/75 reads (73%) | catalogued as COSV59678148; called by muse, mutect2, varscan2
- LAIR2 | c.96G>A p.S32= | Silent (SNP) | VAF 74/146 reads (51%) | catalogued as rs142699455; called by muse, mutect2, varscan2
- LILRA2 | c.1197C>G p.L399= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs1034254196, COSV52189568, COSV52191611; called by muse, varscan2
- LRRC25 | c.813C>T p.I271= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV53251174; called by muse, mutect2, varscan2
- LYL1 | c.369C>T p.I123= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV53400190; called by muse, mutect2, varscan2
- MAFG | c.177C>G p.L59= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1201847725, COSV100155442; called by muse, mutect2
- MTPAP | c.627C>T p.L209= | Silent (SNP) | VAF 94/182 reads (52%) | catalogued as rs577383516, COSV53933492; called by muse, mutect2, varscan2
- MYH7 | c.111C>G p.V37= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV62518444, COSV62519912; called by muse, mutect2, varscan2
- MYO1A | c.2844C>G p.L948= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV55654477; called by muse, mutect2, varscan2
- NCKIPSD | c.1890C>A p.I630= | Silent (SNP) | VAF 58/98 reads (59%) | catalogued as COSV53661605; called by muse, mutect2
- NETO1 | c.213C>T p.I71= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV55007760; called by muse, mutect2, varscan2
- NHS | c.4611G>A p.Q1537= | Silent (SNP) | VAF 52/57 reads (91%) | catalogued as COSV66275941; called by muse, mutect2, varscan2
- NPHP4 | c.3123C>T p.F1041= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs779336075, COSV100976773; ClinVar: likely benign; called by muse, varscan2
- NR3C2 | c.1887A>G p.R629= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs535424312, COSV60991967; called by muse, mutect2
- OBP2A | c.156G>A p.V52= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV100535485; called by muse, mutect2, varscan2
- OSBPL8 | c.1467C>T p.G489= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs768519153, COSV53878996; called by muse, mutect2, varscan2
- PANX3 | c.162C>T p.F54= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs770281606, COSV52512379; called by muse, mutect2, varscan2
- PCDHGA2 | c.294G>A p.Q98= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV53960903; called by muse, mutect2, varscan2
- PDE2A | c.1809C>T p.F603= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV57808269; called by muse, mutect2, varscan2
- PLIN4 | c.1884G>A p.V628= (on ENST00000301286; = p.V643= on NM_001367868.2) | Silent (SNP) | VAF 87/168 reads (52%) | catalogued as COSV56692350; called by muse, mutect2, varscan2
- POC1A | c.1209G>A p.Q403= | Silent (SNP) | VAF 100/157 reads (64%) | catalogued as COSV56591713; called by muse, mutect2, varscan2
- POLR2A | c.477G>A p.E159= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs977539951, COSV59492733; called by muse, mutect2, varscan2
- PROM2 | c.2502G>C p.L834= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as COSV58298442; called by muse, mutect2, varscan2
- RHOBTB1 | c.1749G>A p.L583= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV61958783; called by muse, mutect2, varscan2
- SEMA6D | c.918C>A p.I306= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as COSV60378164; called by muse, mutect2, varscan2
- SEPTIN9 | c.1236C>G p.L412= (on ENST00000427177 / NM_001113491.2; = p.L394= on NM_006640.4) | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs770323969, COSV61205900; called by muse, mutect2, varscan2
- SETX | c.6798C>T p.L2266= | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as COSV56386793; called by muse, mutect2, varscan2
- SETX | c.6699C>T p.F2233= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as COSV56386811; called by muse, mutect2, varscan2
- SLC25A21 | c.276C>T p.F92= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as rs1226128663, COSV58723208; called by muse, mutect2, varscan2
- SMAP2 | c.180G>A p.V60= | Silent (SNP) | VAF 130/166 reads (78%) | catalogued as rs149687192; called by muse, mutect2, varscan2
- SPATA20 | c.2103C>T p.L701= (on ENST00000356488 / NM_001258372.1; = p.L717= on NM_022827.4) | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV50066897; called by muse, mutect2, varscan2
- ST8SIA5 | c.993C>G p.L331= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV59332355; called by muse, mutect2, varscan2
- STAG3 | c.3510G>A p.L1170= | Silent (SNP) | VAF 76/119 reads (64%) | catalogued as COSV57931050; called by muse, mutect2, varscan2
- TBX19 | c.330C>T p.P110= | Silent (SNP) | VAF 56/224 reads (25%) | catalogued as rs148222296; called by muse, mutect2, varscan2
- TKT | c.507C>T p.F169= | Silent (SNP) | VAF 71/99 reads (72%) | catalogued as rs200456564; called by muse, mutect2, varscan2
- TMCO3 | c.1854C>T p.A618= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs766674387, COSV64807870; called by muse, mutect2, varscan2
- TOMM40 | c.291G>A p.Q97= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV52977756; called by muse, mutect2, varscan2
- TRPM2 | c.1182C>T p.F394= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs1313836238, COSV55970522; called by muse, mutect2, varscan2
- TSPEAR | c.1095G>A p.Q365= | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as COSV59964916; called by muse, mutect2, varscan2
- TTN | c.80739C>T p.P26913= (on ENST00000591111; = p.P19489= on NM_003319.4) | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV60105391; called by muse, mutect2, varscan2
- UGGT1 | c.93C>T p.L31= | Silent (SNP) | VAF 52/90 reads (58%) | catalogued as COSV52136550; called by muse, mutect2, varscan2
- ZBTB16 | c.453G>A p.R151= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1328649331, COSV60093847; called by muse, mutect2, varscan2
- ZNF138 | c.276G>A p.V92= (on ENST00000307355 / NM_001367572.1; = p.V66= on NM_006524.4) | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV56465521; called by muse, mutect2, varscan2
- ZNF330 | c.579C>T p.F193= | Silent (SNP) | VAF 18/19 reads (95%) | catalogued as rs775330058; called by muse, varscan2
- ERCC6 | c.1397+7525G>A | Intron (SNP) | VAF 21/92 reads (23%) | catalogued as COSV63390765; called by muse, mutect2, varscan2
- PCDHA3 | c.2394+48C>A | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as COSV63542362; called by muse, mutect2, varscan2
- TAOK2 | chr16:29990858 C>T | 3'Flank (SNP) | VAF 18/58 reads (31%) | catalogued as rs779630364, COSV54230282; called by muse, mutect2, varscan2
- TTN | c.10360+1159G>C | Intron (SNP) | VAF 105/190 reads (55%) | catalogued as COSV60105412; called by muse, mutect2, varscan2
